Gene-level copy-number profile of tumor specimen ALCH-B1ZR-TTP1-A from ALCHEMIST case ALCH-B1ZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.4 years (20,217 days).
Specimen ALCH-B1ZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8251d0a3-4bf4-4897-a3d4-1adfb09c9e09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1ZR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/d7d1ddea-ab2b-4783-96ca-4b4142cdb298

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 1,136; copy number 2: 56,295; copy number 3: 566; copy number 4: 348; copy number 5: 9; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,492,813–131,521,573, 1 gene: SMPD4BP.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:124,887,410–124,887,549, 1 gene (within-gene range 0–2): RNU4-82P.
- chr11:70,862,790–70,872,368, 2 genes (within-gene range 0–2): SHANK2-AS3, MIR3664.
- chr12:113,789,542–113,789,807, 1 gene: DYNLL1P4.
- chr16:70,687,439–70,801,160, 7 genes (within-gene range 0–2): VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr17:3,565,444–3,636,250, 6 genes: TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2.
- chr17:50,627,032–50,631,940, 1 gene (within-gene range 0–2): AC004590.1.
- chr17:63,471,604–63,472,093, 1 gene: PPIAP55.
- chr22:18,110,331–18,177,397, 3 genes (within-gene range 0–1): TUBA8, AC008079.1, USP18.
- chr22:18,361,820–18,518,161, 6 genes: FAM230J, AC011718.1, FAM230A, AC023490.2, FAM247B, GGTLC3.
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:132,943,967–132,965,289, 1 gene, copy number 6 (within-gene range 4–6): LINC01166.
- chr14:100,988,161–100,998,541, 7 genes, copy number 5: SNORD114-27, SNORD114-28, SNORD114-29, SNORD114-30, SNORD114-31, AL132709.5, AL132709.6.
- chr16:90,173,217–90,222,851, 2 genes, copy number 5: LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 908. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
